Gene-level copy-number profile of tumor specimen CDDP-ACJ1-TTP1-A from CDDP_EAGLE case CDDP-ACJ1, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79 years.
Specimen CDDP-ACJ1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b822b304-182c-488f-98f1-525832f8eedb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACJ1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/58a4e0aa-6cc7-4c04-91fe-c012b7f4bf03

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 1,099; copy number 2: 56,718; copy number 3: 522; copy number 4: 12; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr2:90,121,786–90,173,414, 4 genes (within-gene range 0–1): IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr2:90,359,809–90,367,699, 2 genes: AC233263.1, AC233263.7.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr10:38,423,625–38,423,728, 1 gene: RNU6-1118P.
- chr14:18,333,726–18,626,787, 11 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5.
- chr16:35,574,834–35,575,494, 1 gene: C1QL1P1.
- chr21:10,413,477–13,067,033, 10 genes (within-gene range 0–1): BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,095. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
